Somatic mutation profile of tumor specimen TCGA-RD-A8N0-01A (aliquot TCGA-RD-A8N0-01A-12D-A364-08) from TCGA case TCGA-RD-A8N0, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.4 years (19,491 days).
Specimen TCGA-RD-A8N0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3df1ece-4196-4f12-9bc0-9e7173dd7ae4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A8N0-10A (Blood Derived Normal), aliquot TCGA-RD-A8N0-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67c90892-26fc-4bd5-9a84-187b93a8248f

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRDM14 | c.1467C>A p.Y489* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99400554; called by muse, mutect2
- CFAP91 | c.1928T>A p.I643K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2
